Somatic mutation profile of tumor specimen TCGA-DJ-A13P-01A (aliquot TCGA-DJ-A13P-01A-11D-A10S-08) from TCGA case TCGA-DJ-A13P, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage II; Age at diagnosis: 52.8 years (19,297 days).
Specimen TCGA-DJ-A13P-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e34edbb-e597-4a36-a749-2169fec478d1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A13P-10A (Blood Derived Normal), aliquot TCGA-DJ-A13P-10A-01D-A10S-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dede3bd9-c63a-4235-b090-d010881a95de

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 2, 3'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/140 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- KMT2A | c.8153A>T p.D2718V | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV63293103; called by muse, mutect2
- OFD1 | c.1948A>T p.R650* | Nonsense Mutation (SNP) | VAF 43/185 reads (23%) | catalogued as COSV60799228; called by muse, mutect2, varscan2
- PIMREG | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.305); catalogued as COSV51472282; called by muse, mutect2, varscan2
- HOXC12 | c.93G>T p.A31= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as rs763832631, COSV54535757; called by muse, mutect2, varscan2
- PHEX | c.747T>G p.L249= | Silent (SNP) | VAF 27/298 reads (9%) | catalogued as COSV65079421; called by muse, mutect2
- CPLANE1 | c.*5589A>T | 3'UTR (SNP) | VAF 45/116 reads (39%) | catalogued as rs763759036, COSV57075758; called by muse, mutect2, varscan2
